TCGA case TCGA-29-1697 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/42ebd30b-175e-4ece-a806-e55cb7e40e96

Demographics
Sex at birth: female; Race: white; Age at index: 62 years; Vital status: Dead; Days to death: 949 days (2.6 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 62.8 years (22,933 days); Year of diagnosis: 2003; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No.
   Pathology details: Residual tumor measurement: >20 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 28 days; Days to treatment end: 182 days; Number of cycles: 7; Treatment dose: 4,512 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Treatment intent type: Adjuvant; Days to treatment start: 28 days; Days to treatment end: 91 days; Number of cycles: 4; Treatment dose: 11,184 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 111 days; Days to treatment end: 182 days; Number of cycles: 4; Treatment dose: 1,246 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Initial disease status: Recurrent Disease; Days to treatment start: 510 days (1.4 years); Days to treatment end: 535 days (1.5 years); Number of cycles: 4; Treatment dose: 54 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Progressive Disease; Days to treatment start: 552 days (1.5 years); Days to treatment end: 664 days (1.8 years); Number of cycles: 6; Treatment dose: 574 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Doxorubicin; Initial disease status: Recurrent Disease; Days to treatment start: 780 days (2.1 years); Days to treatment end: 843 days (2.3 years); Number of cycles: 3; Treatment dose: 70 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Progressive Disease; Days to treatment start: 878 days (2.4 years); Days to treatment end: 899 days (2.5 years); Number of cycles: 2; Treatment dose: 574 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 927 days (2.5 years); Days to treatment end: 927 days (2.5 years); Treatment dose: 650 mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 927 days (2.5 years); Days to treatment end: 934 days (2.6 years); Number of cycles: 2; Treatment dose: 5 mg; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 64.2 years (23,433 days); Days to diagnosis: 500 days (1.4 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 500 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 500 days (1.4 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 949 days (2.6 years); Disease response: With Tumor.
- ECOG performance status: 1; Timepoint: Other.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-29-1697-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.9; Intermediate dimension: 0.8; Shortest dimension: 0.4.
  Slide TCGA-29-1697-01A-01-BS1: Section location: Bottom; Percent tumor cells: 98; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 0.
  Slide TCGA-29-1697-01A-01-TS1: Section location: Top; Percent tumor cells: 98; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 0.
- Sample TCGA-29-1697-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 4: Therapy regimen: Progression.
- Drug treatment 5: Pharmaceutical therapy drug name: Topotecan HCL; Therapy regimen: Progression.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 949 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 949 days; disease-free interval: event (new tumor event after initially disease-free), 500 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 500 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-29-1697-01A-01D-0559-01): tumor purity 0.98, ploidy 1.71, whole-genome doublings 0.
